Gene-level copy-number profile of tumor specimen TCGA-28-6450-01A from TCGA case TCGA-28-6450, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.7 years (22,177 days).
Specimen TCGA-28-6450-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.022234bf-b9c1-4bb7-8281-e11112239ae4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-28-6450-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fdba3ce5-a8fc-4625-9d8f-c3c263a5c7d6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 143; copy number 1: 4; copy number 2: 5,905; copy number 3: 47; copy number 4: 43,885; copy number 5: 3,195; copy number 6: 5,513; copy number 7: 691; copy number 8: 14; copy number 9: 10; copy number 18: 2; copy number 20: 12; copy number 21: 305; copy number 24: 2; copy number 28: 10; copy number 29: 67; copy number 30: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-28-6450-01A-11D-1694-01): tumor purity 0.76, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 140 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,785,454–7,769,706, 1 gene (within-gene range 0–2): CAMTA1.
- chr1:7,368,942–9,271,337, 54 genes: CAMTA1-IT1, CAMTA1-AS2, CAMTA1-AS1, AL359881.3, AL359881.2, AL359881.1, VAMP3, Z98884.2, PER3, Z98884.1, UTS2, TNFRSF9, AL009183.1, PARK7, Y_RNA, AL034417.4, AL034417.3, ERRFI1, AL034417.2, AL034417.1, AL358876.1, LINC01714, RNU1-7P, AL358876.2, RNU6-991P, SLC45A1, Y_RNA, RERE, RERE-AS1, AL096855.1, AL096855.2, RPL7P11, RPL7P7, Y_RNA, AL357552.1, AL357552.2, RPL23AP19, ENO1, MIR6728, ENO1-AS1, RNU6-304P, HMGN2P17, AL139415.1, AL139415.2, CA6, RN7SL451P, SLC2A7, SLC2A5, AL158048.1, GPR157, MIR34AHG, MIR34A, LNCTAM34A, H6PD.
- chr1:22,517,474–22,603,595, 2 genes (within-gene range 0–2): ZBTB40-IT1, EPHA8.
- chr1:23,162,704–23,484,568, 14 genes (within-gene range 0–2): RNU6-514P, RNU6-135P, HTR1D, AL109936.1, LINC01355, AL109936.9, HNRNPR, ZNF436, ZNF436-AS1, Y_RNA, AL109936.2, TCEA3, AL357134.1, ASAP3.
- chr9:21,186,694–25,844,585, 69 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 422 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,636,604–10,796,650, 1 gene, copy number 21 (within-gene range 2–21): CASZ1.
- chr1:10,895,761–21,176,888, 318 genes, copy number 21–30 (within-gene range 4–30) (broad region; genes not listed).
- chr1:21,217,247–21,345,572, 1 gene, copy number 20 (within-gene range 3–20): ECE1.
- chr1:21,293,290–21,578,410, 10 genes, copy number 20 (within-gene range 2–20): ECE1-AS1, PPP1R11P1, AL592309.1, AL592309.2, NBPF2P, HS6ST1P1, CROCCP5, NBPF3, PFN1P10, ALPL.
- chr1:24,119,771–24,143,140, 1 gene, copy number 20: IL22RA1.
- chr1:62,236,165–62,319,434, 2 genes, copy number 24: KANK4, RNU6-371P.
- chr1:65,248,219–65,761,352, 10 genes, copy number 28 (within-gene range 4–28): DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1, AL513493.1, RN7SL854P.
- chr1:66,533,383–70,531,492, 67 genes, copy number 29 (broad region; genes not listed).
- chr2:10,120,698–10,211,725, 1 gene, copy number 18 (within-gene range 4–18): RRM2.
- chr2:10,192,614–10,192,671, 1 gene, copy number 18: MIR4261.
- chr2:21,221,169–21,970,959, 1 gene, copy number 9 (within-gene range 4–9): AC018742.1.
- chr2:21,607,465–22,536,322, 9 genes, copy number 9 (within-gene range 2–9): AC009411.2, AC009411.1, LINC01822, RN7SL117P, AC096570.1, AC068044.1, AC099799.1, RNA5SP87, LINC01830.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
